Somatic mutation profile of tumor specimen MMRF_1251_1_BM_CD138pos (aliquot MMRF_1251_1_BM_CD138pos_T1_TSE61_L00105) from MMRF case MMRF_1251, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.1 years (15,744 days).
Specimen MMRF_1251_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a85db0eb-23b8-4e81-88ef-3edbc7420b4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1251_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1251_2_PB_Whole_C1_TSE61_L00111; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac62e067-2f25-404a-b86a-3443c9691c8b

The open-access MAF lists 71 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 19, Silent 6, 5'UTR 5, Nonsense Mutation 4, Intron 4, Frame Shift Del 2, 5'Flank 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs564993919; called by muse, mutect2, varscan2
- ASPHD1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as rs1425223647; called by muse, mutect2, varscan2
- C1orf94 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as rs1406847718; called by muse, mutect2, varscan2
- CCDC105 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs1169035282, COSV99479698, COSV99479786; called by muse, mutect2, varscan2
- HMCN1 | c.7279G>A p.V2427I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs764921432; called by muse, mutect2, varscan2
- KALRN | c.5690G>T p.S1897I (on ENST00000360013 / NM_001024660.4; = p.S200I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV52261899, COSV52262103; called by muse, mutect2, varscan2
- MME | c.1877A>T p.Y626F | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852505; called by muse, mutect2, varscan2
- OPLAH | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV101470719, COSV101470736; called by mutect2, varscan2
- OR2T33 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV58814497; called by muse, mutect2, varscan2
- OR4K5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV60002682; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2, varscan2
- PGAP3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs760427744, COSV56130547, COSV56131641; called by muse, mutect2, varscan2
- SEMA3D | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 53/81 reads (65%) | catalogued as COSV52393626; called by muse, mutect2, varscan2
- SYTL3 | c.1738G>A p.V580I (on ENST00000611299 / NM_001242394.1; = p.V512I on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs775230677; called by muse, mutect2, varscan2
- AHR | c.367A>T p.N123Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARGLU1 | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC125 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- CD5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DIS3 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ETV1 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- GUCY2C | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HS3ST1 | c.530T>A p.F177Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- NME8 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NRXN1 | c.3335C>A p.T1112N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM1 | c.2092_2095del p.H698Sfs*8 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | called by pindel, varscan2
- RINT1 | c.1722T>A p.N574K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH1 | c.363A>G p.Q121= | Splice Region (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- SYT1 | c.527del p.G176Afs*7 | Frame Shift Del (DEL) | VAF 53/106 reads (50%) | called by mutect2, pindel, varscan2
- TLN2 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM131 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC14 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- USH2A | c.11846G>C p.G3949A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, varscan2
- VPS11 | c.715A>G p.S239G (on ENST00000620429; = p.S783G on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZMYM2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ZNF804B | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CLEC4C | c.390C>T p.I130= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- LCE1E | c.129C>T p.C43= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV64219816; called by muse, mutect2, varscan2
- MDGA2 | c.2832A>G p.G944= (on ENST00000399232 / NM_001113498.2; = p.G646= on NM_182830.4) | Silent (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1353C>T p.F451= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as rs147576055; called by muse, mutect2, varscan2
- WNT16 | c.450C>T p.D150= (on ENST00000222462 / NM_057168.2; = p.D140= on NM_016087.2) | Silent (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- ZMPSTE24 | c.1299T>A p.S433= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*3323G>A | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- ANXA2R | chr5:43044899 C>T | 5'Flank (SNP) | VAF 32/71 reads (45%) | catalogued as rs1159728261; called by muse, mutect2, varscan2
- B3GAT2 | c.-434del | 5'UTR (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- CBY1 | c.*17del | 3'UTR (DEL) | VAF 41/91 reads (45%) | catalogued as rs1193783076; called by mutect2, pindel, varscan2
- CCDC66 | c.2760+585T>A | Intron (SNP) | VAF 63/107 reads (59%) | called by muse, mutect2, varscan2
- CHST9 | c.241-8469C>T | Intron (SNP) | VAF 35/88 reads (40%) | catalogued as rs975921487; called by muse, mutect2, varscan2
- DNAJB12 | c.*1320C>T | 3'UTR (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2
- DNAJB12 | c.*1318G>T | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2
- DSC2 | c.-139C>A | 5'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- DSTYK | c.*2993G>C | 3'UTR (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- EYS | c.1766+4289G>A | Intron (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- FGA | c.*424C>T | 3'UTR (SNP) | VAF 44/80 reads (55%) | called by muse, mutect2, varscan2
- FLCN | c.871+73G>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FOXL1 | c.*291T>A | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- ITSN2 | c.*695G>A | 3'UTR (SNP) | VAF 28/71 reads (39%) | catalogued as rs916799227; called by muse, mutect2, varscan2
- MBNL1 | c.-96A>C | 5'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- MDM4 | c.*5000G>A | 3'UTR (SNP) | VAF 74/103 reads (72%) | called by muse, mutect2, varscan2
- MTUS1 | c.*482C>T | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- MXI1 | chr10:110286766 C>T | 3'Flank (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*705A>C | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- NFATC4 | c.*1242G>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- NFIB | c.*5500A>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- OPCML | c.*4021C>A | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- PDS5B | c.*772T>C | 3'UTR (SNP) | VAF 24/25 reads (96%) | called by muse, mutect2, varscan2
- PLIN4 | c.*25C>A | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2
- SCIN | c.*408A>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, varscan2
- SPRY4 | c.*2530G>A | 3'UTR (SNP) | VAF 45/86 reads (52%) | catalogued as rs1306083949; called by muse, mutect2, varscan2
- TARDBP | c.-73T>A | 5'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2
- TARDBP | c.-71C>A | 5'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs974776923; called by muse, mutect2
- ZNF721 | c.*1388G>C | 3'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
